Gene-level copy-number profile of tumor specimen TCGA-D7-6820-01A from TCGA case TCGA-D7-6820, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.3 years (23,486 days).
Specimen TCGA-D7-6820-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.2a480667-ec03-4f83-af1f-0cf476636281.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6820-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f9e0d1a-28a5-493f-8383-09217f17e5e5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 222; copy number 2: 17,328; copy number 3: 22,953; copy number 4: 16,181; copy number 5: 1,857; copy number 6: 515; copy number 7: 404; copy number 11: 58; copy number 12: 7; copy number 14: 3; copy number 15: 66; copy number 16: 1; copy number 17: 5; copy number 20: 50; copy number 21: 1; copy number 22: 24; copy number 23: 21; copy number 24: 22; copy number 26: 29; copy number 30: 24; copy number 44: 14; copy number 78: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6820-01A-11D-1881-01): tumor purity 0.69, ploidy 1.57, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:36,281,280–36,387,967, 1 gene (within-gene range 0–2): MYH9.
- chr22:36,335,421–36,396,517, 2 genes: Z82215.1, FO393418.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 743 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:167,721,192–174,160,165, 150 genes, copy number 7 (broad region; genes not listed).
- chr1:177,170,958–179,098,023, 28 genes, copy number 7 (within-gene range 4–7): BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1, AL365357.1, CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69, AL137796.1, MIR4424, AL449106.1, RALGPS2, PTPN2P1, SNORA63, ANGPTL1, FAM20B, AL139132.1, TOR3A.
- chr3:99,215,224–103,630,912, 63 genes, copy number 7–16 (broad region; genes not listed).
- chr8:11,676,959–15,238,431, 88 genes, copy number 15–24 (within-gene range 2–30) (broad region; genes not listed).
- chr8:14,332,555–14,690,619, 3 genes, copy number 30: Y_RNA, RNU6-397P, AC040926.1.
- chr8:28,348,287–30,250,092, 50 genes, copy number 20 (within-gene range 2–20): FBXO16, AC025871.3, AC025871.2, RNU6-178P, AC025871.1, FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1.
- chr8:48,597,458–48,623,895, 2 genes, copy number 23: LINC02847, AC022915.1.
- chr17:39,003,248–40,061,215, 47 genes, copy number 11: AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124.
- chr17:61,679,139–73,208,507, 270 genes, copy number 7–30 (within-gene range 2–30) (broad region; genes not listed).
- chr17:73,283,624–73,312,005, 1 gene, copy number 21 (within-gene range 2–21): CDC42EP4.
- chr20:51,386,957–54,070,594, 39 genes, copy number 11–78 (within-gene range 4–78): NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1.
- chr21:31,559,245–31,628,600, 2 genes, copy number 7: AP000251.1, FBXW11P1.

Autosomal genes at a single copy (total copy number 1): 222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
